TCGA case TCGA-HB-A43Z — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9c9b53e5-cdbe-4510-a839-4a3b5039681b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Alive.

Diagnoses (3)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 58.1 years (21,233 days); Year of diagnosis: 2012; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0; Sites of involvement: Uterus; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 10.
2. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Synchronous primary; Age at diagnosis: 58.1 years (21,238 days); Days to diagnosis: 5 days; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 60.6 years (22,127 days); Days to diagnosis: 894 days (2.4 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 126 days; Disease response: Tumor Free.
- Days to follow up: 484 days (1.3 years); Disease response: Tumor Free.
- Day 894 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 894 days (2.4 years).
- Days to follow up: 1,126 days (3.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 10.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HB-A43Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 910 mg.
  Slide TCGA-HB-A43Z-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-HB-A43Z-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HB-A43Z-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 42; Days from index date to pharmaceutical treatment ended: 105; Pharmaceutical therapy drug name: Gemzar; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 42; Days from index date to pharmaceutical treatment ended: 105; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment ended: 189; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Radiation treatment: Days from index date to radiation therapy started: 207; Days from index date to radiation therapy ended: 239; Radiation therapy type: External; Radiation total dose: 4500; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 25; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Cystic Renal Cell Carcinoma; Days from index date to other malignancy diagnosis: 5.
- Other malignancy form, Surgery: Other malignancy surgery type: Lap. Partial Nephrectomy; Days from index date to other malignancy surgery: 5.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Patient had a synchronous cystic renal cell carcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,126 days; disease-specific survival: no event (censored), 1,126 days; disease-free interval: event (new tumor event after initially disease-free), 894 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 894 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HB-A43Z-01A-11D-A24M-01): tumor purity 0.92, ploidy 2.8, whole-genome doublings 1.
